Gene-level copy-number profile of tumor specimen C3N-01846-01 from CPTAC case C3N-01846, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 69.9 years (25,518 days).
Specimen C3N-01846-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b785fe96-066f-4ee1-8090-50902b388d7e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01846-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/13cc8ef3-724e-493b-a1b8-d63ae76330dd

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 535; copy number 2: 8,648; copy number 3: 24,889; copy number 4: 11,296; copy number 5: 4,688; copy number 6: 3,049; copy number 7: 3,602; copy number 8: 376; copy number 9: 51; copy number 10: 141; copy number 11: 64; copy number 12: 970; copy number 13: 107; copy number 14: 280; copy number 15: 43; copy number 16: 5; copy number 18: 13; copy number 19: 63; copy number 23: 2; copy number 29: 32; copy number 32: 31; copy number 36: 13.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–3): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr8:4,787,332–4,788,584, 1 gene (within-gene range 0–2): PAICSP4.
- chr11:55,602,360–55,607,645, 1 gene: OR4C11.
- chr14:23,969,874–24,051,377, 2 genes (within-gene range 0–3): DHRS4L2, AL136419.1.
- chr17:18,393,480–18,400,961, 1 gene: TBC1D3P4.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 5,793 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–147,626,216, 135 genes, copy number 7 (broad region; genes not listed).
- chr1:232,700,204–248,565,299, 338 genes, copy number 7 (broad region; genes not listed).
- chr1:248,649,838–248,937,043, 16 genes, copy number 7: OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P, RPL23AP25.
- chr2:4,514,204–76,595,678, 1,234 genes, copy number 7 (broad region; genes not listed).
- chr3:113,211,003–169,663,775, 931 genes, copy number 7–11 (broad region; genes not listed).
- chr3:169,720,187–198,123,232, 569 genes, copy number 12–16 (broad region; genes not listed).
- chr4:49,096–23,515,284, 412 genes, copy number 7 (broad region; genes not listed).
- chr4:49,486,926–59,180,414, 144 genes, copy number 7–29 (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 12 (broad region; genes not listed).
- chr7:55,764,797–56,632,727, 46 genes, copy number 8–10: PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17, PSPH, CCT6A, SNORA22B, SNORA15, SUMF2, PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, CCNJP1, AC073136.1, AC073136.2, AC093392.1, RNU6-1335P, SEPTIN14P24, CICP8, AC093392.2, RNU6-1052P, AC092423.1, AC092447.7, AC092447.10, AC092447.4, RBM22P3, AC092447.8, NMD3P2, AC092447.3, AC092447.5, VN1R25P, AC092447.2, AC092447.6, AC092447.1, AC092447.9, TRIM60P16.
- chr7:62,275,361–119,179,149, 1,062 genes, copy number 7–36 (broad region; genes not listed).
- chr8:33,604,856–34,039,104, 1 gene, copy number 10 (within-gene range 2–10): AF279873.3.
- chr8:33,715,784–40,897,833, 120 genes, copy number 10–18 (broad region; genes not listed).
- chr9:60,914,407–61,453,030, 12 genes, copy number 12–18: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr14:18,333,726–19,700,650, 68 genes, copy number 7 (broad region; genes not listed).
- chr21:7,744,962–8,454,792, 26 genes, copy number 7: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.

Autosomal genes at a single copy (total copy number 1): 22. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
